Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A26A, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A26A-06A (Metastatic).

[page 1 of 2]
1CΔ-0-3

Melanoma, malignant. Nos 8720/3

Site: Skin, back C44.5 fur 4/27/11

SPECIMENS:

- A. IN TRANSIT MELANOMA RIGHT BACK
- B. ADDITIONAL LATERAL MARGIN
- C. ADDITIONAL MEDIAL MARGIN

SPECIMEN(S):

- A. IN TRANSIT MELANOMA RIGHT BACK
- B. ADDITIONAL LATERAL MARGIN
- C. ADDITIONAL MEDIAL MARGIN

GROSS DESCRIPTION:

A. IN-TRANSIT MELANOMA RIGHT BACK

Received fresh labeled with the patient's name and "in transit melanoma, right back, stitch lateral" is an oval-shaped piece of tan skin measuring 5 x 4.6 x 2 cm. Extending from the lateral tip is a 3.9 cm well healed scar. In the deep portion of the specimen is attached skeletal muscle measuring 2.7 x 1.9 x 0.5 cm. The 12 to 3 to 6 o'clock margin is inked orange, 6 to 9 to 12 o'clock margin is inked blue, and the deep margin is inked black. The specimen is bisected. There is a well circumscribed firm tan mass measuring 2.1 cm in greatest dimension. It is located 0.55 cm from the skin surface, 1.2 cm from the inferior, superior, lateral, and medial margins, 2.2 cm from the deep margin. Portions of the mass are submitted for procurement. Specimen is submitted entirely as follows:

- A1: shave section a lateral tip
- A2-A3: one complete cross lateral to mass
- A4- A5: one cross section lateral to mass
- A6-A7: one cross section including mass
- A8: Deep margin
- A9-A10: complete cross section including deep margin and mass
- A11-A12: complete cross section
- A13-A14: one complete cross section medial to mass
- A15: shave medial tip

B. ADDITIONAL LATERAL MARGIN

Received in formalin labeled with the patient's name and "additional lateral margin, stitch final lateral" is an arrow-shaped piece of unremarkable tan skin measuring 5.0 x 4.0 x 1.5 cm. The 12 to 4 o'clock position is inked orange, the 4 to 8 o'clock position is inked black, and the 8 to 12 o'clock position is inked blue. The specimen is serially sectioned from lateral to medial and submitted entirely as follows:

- B1: lateral tip
- B2-B7: cross sections submitted from lateral to medial
- B8: medial tips

C. ADDITIONAL MEDIAL MARGIN

Received in formalin labeled with the patient's name and "additional medial margin, stitch final medial" is an arrow-shaped piece of tan skin measuring 3.0 x 2.5 x 2.2 cm. The 12 to 4 o'clock position is inked orange, the 4 to 8 o'clock position is inked black, the 8 to 12 o'clock position is inked blue. The specimen is serially sectioned from medial to lateral and submitted entirely:

- C1: medial tip
- C2-C3: cross sections serially submitted from medial to lateral
- C4: shave section of lateral margin

RESULTS:

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A1

Population: Tumor Cells

Stain/Marker:Result: Comment:

S-100 Positive

A103,MELAN-A Negative

HMB 45 Negative

[page 2 of 2]
The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of the The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the FDA. The use of these tests if they have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

DIAGNOSIS:

- A. SKIN, RIGHT BACK, EXCISION:
- MALIGNANT MELANOMA IN TRANSIT, MULTIPLE FOCI (SEE NOTE).
- LARGEST FOCUS IS 21 MM.
- PRESENT AT LATERAL MARGIN.
- WITHIN 2 MM OF THE DEEP MARGIN.
- LYMPHOVASCULAR INVASION IS PRESENT.
- SKELETAL MUSCLE, NEGATIVE FOR TUMOR.
- FOCAL PREVIOUS BIOPSY SITE CHANGES.
- B. SKIN, ADDITIONAL LATERAL MARGIN, EXCISION:
- SKIN, NEGATIVE FOR TUMOR.
- C. SKIN, ADDITIONAL MEDIAL MARGIN, EXCISION:
- MALIGNANT MELANOMA IN TRANSIT, MULTIPLE FOCI.
- LARGEST FOCUS IS 2 MM.
- TUMOR IS WITHIN 1 MM OF THE DEEP MARGIN.
- DESIGNATED FINAL MEDIAL MARGIN, NEGATIVE FOR TUMOR.
- LYMPHOVASCULAR INVASION IS PRESENT.

NOTE: In the main excisional specimen (specimen A), there are at least 3 foci of tumor and the tumor is within 2 mm of the deep margin at the medial and mid aspects. Immunostains were performed on the lateral margin of specimen A (section A1). The focus suspicious for tumor was S100 positive and HMB45 and Melan-A negative. Despite the lack of staining with the latter two markers, the area was felt to be consistent with melanoma based on the histologic features and S100 staining. The final medial and lateral margins (specimens B & C) are negative for tumor. In specimen C, there are at least two foci of tumor.

CLINICAL HISTORY:

Year Old with In-Transit Melanoma Right Back

Gross Dictation:., Pathologist, ()
Microscopic/Diagnostic Dictation: Pathologist
Final Review:., Pathologist
Final: Pathologist,

Diagnostic Discrepancy		/
Stain Discrepancy		/
Primary Malignancy History		/
Just Synchronous Primary Note 1		/

Source: NCI Genomic Data Commons file 7516c2b2-e01b-4057-8f5e-0290b6d31915 (TCGA-GN-A26A.5F794422-0A58-4224-8108-E0E4DE11D4C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).